Surgical pathology report (de-identified scan), TCGA case TCGA-DE-A69J, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of North Carolina, specimen TCGA-DE-A69J-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3

Carcinoma, papillary
Thyroid 8260/3

Site: Thyroid NOS
C73.9

9/5/13

Diagnosis:

A: Thyroid, total thyroidectomy

Tumor histologic type: papillary thyroid carcinoma, multifocal

Tumor size: there are 2 nodules of carcinoma, right upper pole 2.5 cm in greatest dimension, right lower pole 1.7 cm in greatest dimension

Tumor focality & laterality: multifocal, both tumors are in the right thyroid

Tumor capsule: not present

Extent of invasion:

Capsular Invasion: not identified

Lymphovascular invasion: not identified

Blood vascular invasion: not identified

Extra thyroidal extension: not identified

Surgical margins: surgical margins free of tumor

Status of thyroid gland away from tumor: multinodular goiter with extensive fibrosis and calcification

Lymph nodes: none present in specimen

Other significant findings: one parathyroid gland is present (block A1), without pathologic abnormality

AJCC Pathologic TNM Stage: pT2 pNx

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

-year-old with thyroid cancer.

Gross Description:

Received is one appropriately labeled container, additionally labeled "total thyroid, stitch left superior pole"

[page 2 of 3]
Specimen fixation: formalin

Type of specimen: total thyroidectomy

Size and weight of specimen: 35.4 gm, 6.5 x 2.8 x 2.5 cm right lobe, 6.3 x 3.0 x 1.3 cm left lobe and isthmus

Orientation: Suture: left superior pole

Inking: anterior=blue, posterior=black, isthmus=yellow

Tumor location: right superior pole and right inferior pole

Focalilty: multifocal

Dominant tumor: present, right superior pole

Tumor description: The tumors are well circumscribed, solid, fleshy, friable and pink/tan nodules.

Tumor size: The dominate tumor nodule in the right upper pole is 2.5 x 2.2 x 2.1 cm, and in the right lower pole is 1.7 x 1.3 x 1.0 cm.

Confinement / non-confinement: appears confined

Distance of tumor to capsule/inked surgical margins: Each tumor nodule is within 0.1 cm of the blue inked anterior margin, and 0.1 cm of the black inked posterior margin.

Appearance of thyroid gland away from tumor: dark red/brown and homogeneous

Other findings: Adjacent to the smaller nodule in the right lower lobe is a 3.1 x 1.9 x 1.7 cm variegated fibrotic nodule which is well circumscribed and has a dark red/brown colloid cut surface. It is located 0.5 cm inferior to the dominate nodule and 0.2 cm from the smaller nodule.

Parathyroids: not grossly seen

Lymph nodes: n/a

Tissue submitted for special investigations: tumor and normal are given to Tissue Procurement

Digital photograph taken: no

Block Summary: (Inking: anterior=blue, posterior=black, isthmus=yellow)

[page 3 of 3]
A1-A3 - representative sections from left lobe, superior towards inferior, respectively (A3 contains small nodule in left lower lobe)

A4-A6 - dominate nodule, right upper lobe

A7-A8 - smaller nodule, right lower lobe

A9-A10 - nodule with fibrous capsule, right lower lobe

Tissue remains in formalin.

Hist/AA Discrepancy		✓
Review: KMA		

Source: NCI Genomic Data Commons file 9ea1e115-e8af-4328-9732-99bf01f97e06 (TCGA-DE-A69J.90A9DDB6-4DCF-4467-908F-25A5481B5D70.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).